Somatic mutation profile of tumor specimen C3N-02723-01 (aliquot CPT0176220006) from CPTAC case C3N-02723, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 86.5 years (31,587 days).
Specimen C3N-02723-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da805cd6-1f31-4360-99be-4dfea79c4abc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02723-71 (Blood Derived Normal), aliquot CPT0176340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9636f5a-52ee-4b0e-b411-806bd1e47e3d

The open-access MAF lists 72 somatic variants for this specimen: 42 protein-altering or splice-affecting, 21 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 21, 3'UTR 4, Intron 3, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APAF1 | c.2510C>T p.T837M (on ENST00000551964 / NM_181861.2; = p.T826M on NM_013229.3) | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as rs200461221, COSV59667778; called by muse, mutect2, varscan2
- ARMCX1 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 32/371 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.077); catalogued as COSV65704912; called by muse, mutect2
- BAP1 | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 78/481 reads (16%) | catalogued as COSV56235325, COSV56238458; called by muse, mutect2, varscan2
- C6orf15 | c.68-2A>T p.X23_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV52537152; called by muse, mutect2, varscan2
- CCDC22 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1557115222; called by muse, mutect2, varscan2
- EGFR | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.034); catalogued as COSV51782203; called by muse, mutect2
- GABRP | c.1247A>G p.H416R | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1290926314, COSV54661385; called by muse, mutect2, varscan2
- NIN | c.4549G>C p.E1517Q (on ENST00000382041 / NM_182946.1; = p.E804Q on NM_016350.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55402377; called by muse, varscan2
- PKN1 | c.2293+1G>A p.X765_splice | Splice Site (SNP) | VAF 13/96 reads (14%) | catalogued as rs866516000; called by muse, mutect2, varscan2
- RP1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 64/479 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs373574136, CM025393; called by muse, mutect2, varscan2
- SH2D2A | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV63884617; called by muse, mutect2, varscan2
- STXBP2 | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs374719886; called by muse, mutect2, varscan2
- TRAPPC9 | c.2406G>T p.E802D | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV66909389; called by muse, mutect2, varscan2
- ZNF710 | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.558); catalogued as rs780811099; called by muse, mutect2, varscan2
- ACSF2 | c.597_598insTT p.A200Lfs*7 | Frame Shift Ins (INS) | VAF 35/310 reads (11%) | called by mutect2, pindel, varscan2
- ACTB | c.700T>C p.S234P | Missense Mutation (SNP) | VAF 86/604 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEACAM4 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- CFAP54 | c.962del p.L321Wfs*7 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel, varscan2
- DDR1 | c.712_713del p.L238Gfs*2 | Frame Shift Del (DEL) | VAF 21/195 reads (11%) | called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.963G>T p.S321= | Splice Region (SNP) | VAF 16/64 reads (25%) | called by muse, varscan2
- G6PC | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM6 | c.1500T>A p.D500E | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- HNRNPUL1 | c.1039A>C p.K347Q | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- KATNIP | c.3172C>A p.H1058N | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAB21L4 | c.1070C>T p.A357V (on ENST00000388934 / NM_001085437.3; = p.A189V on NM_024861.4) | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MACROH2A1 | c.363dup p.G122Rfs*26 | Frame Shift Ins (INS) | VAF 78/411 reads (19%) | called by mutect2, pindel, varscan2
- MAP1A | c.499A>C p.N167H | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- MAST1 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- MIA2 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBAS | c.2699C>A p.T900N | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- POLRMT | c.1991T>A p.L664Q | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC31A1 | c.421A>T p.I141F | Missense Mutation (SNP) | VAF 51/683 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); called by muse, mutect2
- SNRNP200 | c.4239C>A p.S1413R | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TAB3 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- TAF1D | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- TLN2 | c.5859del p.E1953Dfs*53 | Frame Shift Del (DEL) | VAF 70/539 reads (13%) | called by mutect2, pindel, varscan2
- TMPRSS6 | c.1625G>T p.C542F | Missense Mutation (SNP) | VAF 31/665 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM67 | c.446C>A p.S149* | Nonsense Mutation (SNP) | VAF 32/315 reads (10%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- URGCP | c.431C>T p.P144L (on ENST00000453200 / NM_001077663.3; = p.P135L on NM_017920.4) | Missense Mutation (SNP) | VAF 63/388 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR19 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- YLPM1 | c.4402G>A p.E1468K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARID1A | c.4647C>T p.G1549= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- C16orf86 | c.216A>G p.G72= | Silent (SNP) | VAF 51/392 reads (13%) | called by muse, mutect2, varscan2
- CHST7 | c.90C>T p.S30= | Silent (SNP) | VAF 75/580 reads (13%) | catalogued as rs1193550030; called by muse, mutect2, varscan2
- CLDN15 | c.561T>C p.S187= | Silent (SNP) | VAF 24/241 reads (10%) | called by muse, mutect2
- CSMD1 | c.3039G>C p.L1013= (on ENST00000520002; = p.L1012= on NM_033225.6) | Silent (SNP) | VAF 57/625 reads (9%) | called by muse, mutect2
- LRCH4 | c.123C>T p.A41= | Silent (SNP) | VAF 56/448 reads (13%) | catalogued as rs1310915116; called by muse, mutect2, varscan2
- LTBP1 | c.2049C>G p.V683= (on ENST00000404816 / NM_206943.4; = p.V357= on NM_000627.4) | Silent (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- MPLKIP | c.429A>G p.S143= | Silent (SNP) | VAF 58/482 reads (12%) | catalogued as rs867994627; called by muse, mutect2, varscan2
- MYL10 | c.657C>A p.I219= | Silent (SNP) | VAF 37/256 reads (14%) | called by muse, mutect2, varscan2
- NFAM1 | c.144C>T p.T48= | Silent (SNP) | VAF 23/164 reads (14%) | catalogued as rs767203917, COSV61195776; called by muse, mutect2, varscan2
- NLRP14 | c.1623A>G p.V541= | Silent (SNP) | VAF 50/388 reads (13%) | called by muse, mutect2, varscan2
- PARD3B | c.2511G>A p.T837= (on ENST00000406610 / NM_001302769.2; = p.T768= on NM_057177.7) | Silent (SNP) | VAF 25/259 reads (10%) | catalogued as rs750239561, COSV62510096; called by muse, mutect2, varscan2
- PCDHGB1 | c.525C>T p.F175= | Silent (SNP) | VAF 71/231 reads (31%) | called by muse, mutect2, varscan2
- PNPT1 | c.735C>T p.I245= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- RAVER2 | c.822T>C p.F274= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- RIPPLY3 | c.288G>A p.G96= | Silent (SNP) | VAF 24/195 reads (12%) | catalogued as rs776666809, COSV61566669; called by muse, mutect2
- ROBO4 | c.2613C>T p.G871= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- SEMA4G | c.1923C>A p.T641= (on ENST00000370250; = p.T646= on NM_017893.3) | Silent (SNP) | VAF 59/512 reads (12%) | called by muse, mutect2, varscan2
- SPIN4 | c.69C>T p.H23= | Silent (SNP) | VAF 23/179 reads (13%) | called by muse, mutect2
- ST6GAL1 | c.396C>T p.G132= | Silent (SNP) | VAF 48/278 reads (17%) | called by muse, mutect2, varscan2
- UBE2H | c.450G>A p.T150= | Silent (SNP) | VAF 28/323 reads (9%) | catalogued as rs764179898; called by muse, mutect2
- CARD19 | c.*1137C>A | 3'UTR (SNP) | VAF 27/420 reads (6%) | called by muse, mutect2
- CHTF8 | chr16:69132504 del CGCGGCGC | 5'Flank (DEL) | VAF 29/240 reads (12%) | called by mutect2, pindel, varscan2
- DNAH14 | c.1032+133G>C | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- MTG1 | c.573+26G>A | Intron (SNP) | VAF 29/254 reads (11%) | called by muse, mutect2, varscan2
- PARL | c.511+27C>G | Intron (SNP) | VAF 29/289 reads (10%) | called by muse, mutect2, varscan2
- PPP6R3 | c.*1781T>C | 3'UTR (SNP) | VAF 83/578 reads (14%) | catalogued as rs1427822980; called by muse, mutect2, varscan2
- SLC9A9 | c.*31G>T | 3'UTR (SNP) | VAF 21/158 reads (13%) | called by muse, varscan2
- SNORD116-10 | n.92_95del | RNA (DEL) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
- TESPA1 | c.*38G>A | 3'UTR (SNP) | VAF 29/176 reads (16%) | catalogued as rs1406340655; called by muse, mutect2
